Gene-level copy-number profile of tumor specimen TCGA-J9-A8CL-01A from TCGA case TCGA-J9-A8CL, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 66.1 years (24,145 days).
Specimen TCGA-J9-A8CL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.181e5a0d-d640-4450-8b99-44b7ef4f64c2.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-J9-A8CL-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 817 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/54629804-77c1-40ae-8006-c44ded5bb208

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 66; copy number 1: 7,264; copy number 2: 41,896; copy number 3: 9,664; copy number 4: 508; copy number 5: 129; copy number 6: 275; copy number 7: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-J9-A8CL-01A-11D-A34T-01): tumor purity 0.75, ploidy 2.05, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 66 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:37,811,589–38,945,596, 23 genes (within-gene range 0–4): GDNF-AS1, GDNF, LINC02117, AC008869.1, LINC02110, AC034226.1, LINC02119, AC010338.1, EGFLAM, EGFLAM-AS4, EGFLAM-AS3, EGFLAM-AS2, EGFLAM-AS1, AC091839.1, AC010457.1, LIFR, LIFR-AS1, MIR3650, AC010425.1, OSMR-AS1, AC091435.1, AC091435.2, OSMR.
- chr5:39,371,675–39,524,726, 2 genes (within-gene range 0–4): DAB2, LINC02104.
- chr17:39,461,486–40,172,171, 35 genes (within-gene range 0–2): CDK12, RNU6-233P, AC009283.1, NEUROD2, AC087491.1, PPP1R1B, STARD3, TCAP, PNMT, PGAP3, ERBB2, MIR4728, MIEN1, GRB7, IKZF3, KRT8P34, AC090844.1, ZPBP2, GSDMB, ORMDL3, AC090844.2, LRRC3C, GSDMA, PSMD3, AC090844.3, CSF3, MED24, MIR6884, SNORD124, THRA, NR1D1, AC068669.1, MSL1, CASC3, MIR6866.
- chr17:77,877,330–78,108,835, 6 genes (within-gene range 0–1): LINC01973, RNU1-80P, TNRC6C, AC015804.1, UBE2V2P2, RNU6-625P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 408 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:168,497,052–168,928,457, 1 gene, copy number 5 (within-gene range 4–5): PALLD.
- chr4:168,647,896–169,270,956, 12 genes, copy number 5: PALLD-AS1, RNU6-1336P, RPL9P16, AC080188.1, AC080188.2, CBR4, RNU6-853P, RNY4P17, AC021151.1, SH3RF1, RPL6P12, AC096741.1.
- chr5:164,935,162–164,935,268, 1 gene, copy number 6: RNU6-209P.
- chr8:77,399,072–81,924,348, 83 genes, copy number 6 (broad region; genes not listed).
- chr8:82,098,451–82,160,577, 1 gene, copy number 6: LINC02839.
- chr8:89,412,621–93,166,850, 50 genes, copy number 6: KRT8P4, AF117829.1, RIPK2, COX6B1P6, AF117829.2, RNU6-925P, OSGIN2, NBN, DECR1, CALB1, AC004083.1, LINC00534, RNA5SP273, LINC01030, TMEM64, AC106038.1, AC106038.2, NECAB1, AC103770.1, C8orf88, PIP4P2, AC087439.1, AC087439.2, OTUD6B-AS1, OTUD6B, LRRC69, CPP, MIR4661, SLC26A7, AC103409.1, RN7SKP231, PRR13P7, MRPS16P1, RUNX1T1, AF181450.1, AC104339.1, AC022695.1, AC022695.2, AC022695.3, AC091096.1, AC104211.1, AC104211.3, FLJ46284, AC104211.2, AC117834.2, AC117834.1, TRIQK, IRF5P1, MIR8084, C8orf87.
- chr8:119,711,830–119,874,488, 7 genes, copy number 6: RN7SKP153, TAF2, AP005717.2, DSCC1, AC021945.1, RN7SL396P, AP005717.1.
- chr8:126,556,323–127,419,050, 1 gene, copy number 5 (within-gene range 3–5): PCAT1.
- chr8:126,671,522–131,040,909, 56 genes, copy number 5–7 (within-gene range 3–7): RNU11-4P, AC024382.1, CASC19, PRNCR1, AC020688.1, AC018714.2, CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, AC108925.1, CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208, RN7SKP226, AC100822.1, LINC00824, CCDC26, AC103833.2, AC103833.1, RN7SKP206, AC011257.1, MIR3686, AC103718.1, MTRF1LP2, GSDMC, AC022973.5, CYRIB, AC022973.2, AC022973.1, AC022973.4, AC022973.3, AC131568.1, RNU7-181P, MIR5194, ASAP1, RNU6-1255P, ASAP1-IT2, AC103725.1, AC009682.1, AC139019.1, AC090987.1, ADCY8, AC103726.1, AC103726.2.
- chr10:90,402,521–90,628,852, 1 gene, copy number 5 (within-gene range 4–5): LINC02653.
- chr10:90,622,143–93,077,885, 51 genes, copy number 5: AL390862.1, HTR7, RPP30, Y_RNA, ANKRD1, RNU6-740P, AL365434.1, AL365434.2, LINC00502, DDX18P6, NUDT9P1, AL731553.1, PCGF5, HECTD2, AL161798.1, RPS27P1, PPP1R3C, GAPDHP28, FAF2P1, TNKS2-AS1, TNKS2, SRP9P1, AL359198.2, FGFBP3, AL359198.1, BTAF1, CPEB3, AL365398.1, SDHCP2, EIF4A1P8, AL158040.1, NHP2P1, Y_RNA, MARCHF5, RNY3P12, MARK2P9, AL161652.1, IDE, KIF11, RPL11P4, RN7SL644P, EIF2S2P3, HHEX, Y_RNA, EXOC6, AL392103.1, AL358613.1, CYP26C1, AL358613.3, AL358613.2, CYP26A1.
- chr11:66,590,176–69,775,341, 130 genes, copy number 6 (broad region; genes not listed).
- chr14:63,761,899–64,226,433, 1 gene, copy number 5 (within-gene range 3–5): SYNE2.
- chr14:64,084,232–64,387,986, 6 genes, copy number 5: ESR2, MIR548H1, AL161756.1, TEX21P, AL161756.3, AL161756.2.
- chr19:7,069,703–7,383,385, 3 genes, copy number 6 (within-gene range 3–6): ZNF557, INSR, AC119396.1.
- chr20:8,831,186–8,999,100, 4 genes, copy number 5: RNU105B, AL445567.1, AL445567.2, Metazoa_SRP.

Autosomal genes at a single copy (total copy number 1): 5,069. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
